Surgical pathology report (de-identified scan), TCGA case TCGA-61-2097, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2097-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIGHT ADNEXA, 223 GRAMS, RIGHT SALPINGO-OOPHORECTOMY -

- A. MIXED PAPILLARY SEROUS AND ENDOMETRIOID ADENOCARCINOMA, MODERATELY DIFFERENTIATED OF THE RIGHT OVARY.
- B. LYMPHOVASCULAR PERMEATION IS IDENTIFIED.
- C. FOCI OF ENDOSALPINGIOSIS.
- D. MESO- OVARY AND PARAOVARIAN ADHESION INVOLVED BY TUMOR.
- E. RIGHT FALLOPIAN TUBE, NEGATIVE FOR TUMOR.
- F. RIGHT PARATUBAL CYST NEGATIVE FOR TUMOR.

PART 2: LEFT ADNEXA, 124 GRAMS, LEFT SALPINGO-OOPHORECTOMY -

- A. MIXED SEROUS AND ENDOMETRIOID ADENOCARCINOMA, MODERATELY DIFFERENTIATED OF THE LEFT OVARY.
- B. MESO- OVARY AND PARAOVARIAN ADHESION INVOLVED BY TUMOR.
- C. LEFT FALLOPIAN TUBE, NEGATIVE FOR TUMOR.
- D. LEFT MESOSALPINX IS INVOLVED BY TUMOR.

PART 3: UTERUS, 40 GRAMS, TOTAL ABDOMINAL HYSTERECTOMY -

- A. CHRONIC CERVICITIS.
- B. INACTIVE ENDOMETRIUM IN PROLIFERATIVE PATTERN.
- C. ADENOMYOSIS.
- D. UTERINE SEROSA INVOLVED BY TUMOR.

PART 4: TUMOR OF THE SIGMOID, BIOPSY -

FIBROFATTY TISSUE INVOLVED BY METASTATIC ADENOCARCINOMA.

PART 5: BLADDER, PERITONEUM, BIOPSY -

FIBROFATTY TISSUE INVOLVED BY METASTATIC ADENOCARCINOMA.

PART 6: OMENTUM -

OMENTAL FAT WITH FOCAL SUPERFICIAL INVOLVEMENT BY ADENOCARCINOMA, CHRONIC INFLAMMATION AND MESOTHELIAL PROLIFERATION.

PART 7: ABDOMINAL WALL, BIOPSY -

FIBROFATTY TISSUE WITH SUPERFICIAL TUMOR DEPOSITS AND CHRONIC INFLAMMATION.

Source: NCI Genomic Data Commons file 5cf44b36-aae4-4e0a-a2da-363a2875ba01 (TCGA-61-2097.6D23149D-A9B0-422F-A560-BC1B4A3B99D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).